TARGET case TARGET-30-PALRIA — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/809b2ef4-fcca-5341-bf13-c533ceed3ab0

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.2; Tissue or organ of origin: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 1.9 years (685 days); Year of diagnosis: 2002; Days to last follow up: 4,080 days (11.2 years); Cog neuroblastoma risk group: Low Risk; Inpc grade: Differentiating; INSS stage: Stage 1; Mitosis karyorrhexis index: Low.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 4,080 days (11.2 years); Event-free: no event (relapse, second malignancy or death) recorded through day 4,080; Year of follow up: 2013.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PALRIA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PALRIA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 4080
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.9
- Histology: Favorable
- MKI: Low
- ICDO Description: Abdomen, NOS Abdominal wall, NOS Intra-abdominal site, NOS
